Gene-level copy-number profile of tumor specimen BLGSP-71-06-00159-01B from CGCI case BLGSP-71-06-00159, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 2.7 years (980 days).
Specimen BLGSP-71-06-00159-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5a6e9427-d31f-4d0d-92b0-921879400c07.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00159-12A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/b9df979b-a4a1-4fef-b0aa-1a4becd89a28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 132; copy number 1: 3,610; copy number 2: 53,314; copy number 3: 1,846.

Homozygous deletions (total copy number 0; autosomes only): 132 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 3 genes (within-gene range 0–3): MALLP2, AC244205.1, MIR4436A.
- chr8:7,891,003–7,896,716, 2 genes: HSPD1P2, DEFB4A.
- chr14:105,851,705–106,211,453, 65 genes (within-gene range 0–3) (broad region; genes not listed).
- chr22:22,420,326–22,893,818, 62 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
